Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A3A9, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A3A9-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Right lobe liver (965 grams, 15 x 15 x 9 cm).

A1, A2, A3, A4, A5, A6

DIAGNOSIS:

Liver, left lobe, hepatectomy: Hepatocellular carcinoma forming a 10 cm mass with 1 satellite nodule (7 cm in greatest dimension). The hepatic capsule is involved with extension into but not through the adherent portion of the diaphragm. Extratumoral vascular invasion is not identified. The tumor is partially encapsulated, infiltration of parenchyma being of the pushing type. The non-neoplastic liver is noncirrhotic. The surgical margins are negative for tumor.

ICD-O-3

Carcinoma, hepatocellular, NOS 8170/3

Site: Liver C22.0

hw 9/22/11

For Malignancy History		X

Source: NCI Genomic Data Commons file 6e1b2cab-dcc4-4ace-bac2-f1f73ab1d967 (TCGA-DD-A3A9.59B64E76-42CB-421D-B8A7-36F7050BA5E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).